Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A8MV, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A8MV-01A (Primary Tumor).

[page 1 of 2]
Sex: Male

Printed :

Anatomical Pathology

Page 1 of 3

Lab #:

ICB-0-3

adenocarcinoma, intestinal type 8144/3

CLINICAL NOTES

Site: Stomach, body C16.7 1/22/14

Adenocarcinoma stomach. Radical total gastrectomy. Stomach and specimen of proximal proximal and coeliac lymph nodes.

MACROSCOPIC DESCRIPTION

Three specimen containers received.

1. Specimen container 1 labelled "stomach": The specimen consists of stomach and omentum. The stomach measures approximately 180 x 65 x 30mm. The serosal surface of the stomach appears unremarkable. The stomach is received opened along the greater curvature. Along the anterior aspect of the lesser curvature is a large soft smooth pale tan and dark tan polypoid mass 30 x 25 x 20mm. Immediately proximal to this is an area of ragged mucosa approximately 25 x 17mm. Tissue has previously been taken for a research project, with an incision edistal to the tumour 20mm in length. The mucosa elsewhere is unremarkable. Blocks selected: 1a- proximal resection margin (blue). 1b- distal resection margin (red). 1c- representative section of tumour. 1d and e - sections through ragged area proximal to tumour. 1f and g - composite block of tumour and underlying tumour. 1h- further section of tumour and stomach. Note that the depth of invasion is unclear macroscopically. 1i and 1j- lymph nodes from lesser curvature. The omentum measures an aggregate approximately 250 x 100 x 30mm. The omentum appears normal. 1k - lymph nodes from greater curvature.

2. Specimen container 2 labelled "proximal stomach": The specimen consists of a triangular portion of stomach 75 x 45 x 15mm. A single row of staples 80mm in length is present. The mucosa appears normal. No focal lesions are identified. The serosal aspect is mildly congested but glistening. Blocks selected: 2a and 2b- representative sections. Note that the staple margin has been inked blue.

3. Specimen container 3 labelled "coeliac gland": The specimen consists of a single fragment of glistening pale cream tissue 6 x 3 x 3mm. Blocks selected: 3a-1 all embedded.

MICROSCOPIC DESCRIPTION

COPY

[page 2 of 2]
Sex: Male

Printed :

Anatomical Pathology

Page 2 of 3

1. The polypoid mass arising in lesser curvature along the anterior gastric body is a moderately differentiated intestinal type adenocarcinoma, whereas the adjacent ragged gastric mucosa in continuation with the tumour, shows infiltration by poorly differentiated small glands or diffusely permeating in singly arranged or clusters of bizarre neoplastic cells, extending through the full thickness of the gastric wall into within 0.1mm of the serosal surface. Frequent intralymphovascular tumour invasion is seen. Sections from both proximal and distal portions show focal intestinal metaplasia associated with mild to moderate epithelial dysplasia, extending to within 15mm of the proximal gastric resection margin. Tumour metastasis is seen in 8 out of 11 lesser curvature lymph nodes and 1 out of 5 greater curvature nodes.

2. Circumferential sections of the body type gastric mucosa show focal low-grade epithelial dysplasia on the background of intestinal metaplasia with associated moderate chronic superficial gastritis. Helicobacter-like organisms are not seen.

3. Section of the lymph node shows no tumour deposit.

PATHOLOGIST'S OPINION

1. Distal partial gastrectomy

- Poorly differentiated intestinal type adenocarcinoma, arising in lesser curvature of the anterior gastric body;
- 45mm in maximum dimension; full-thickness tumour involvement of the gastric wall with being less than 0.1mm of the circumferential margin; clear of both proximal and distal margins;
- Tumour metastasis in 8 out of 11 lesser curvature nodes and 1 of 5 greater curvature nodes;
- Extensive intestinal metaplasia of the non-neoplastic gastric mucosa with focal low-grade epithelial dysplasia.

2. Proximal stomach - Body type gastric mucosa showing focal intestinal metaplasia associated with low-grade epithelial dysplasia and moderate superficial chronic gastritis.

3. Coeliac gland - lymph node showing no tumour deposit.

Pathologist:

Criteria	10/23/13	Yes	No

COPY

Source: NCI Genomic Data Commons file d4e3b4f7-94d8-4104-a187-fa2bfed5270b (TCGA-RD-A8MV.CFD084BF-ABD8-4B7A-9A8A-EAF2F62B1CEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).